MMRF case MMRF_2570 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c27ab9c4-03ad-46de-abfb-2ffcb5a92790

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 61.2 years (22,368 days); ISS stage: I; Days to last known disease status: 659 days (1.8 years); Days to last follow up: 659 days (1.8 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 101 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 107 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 106 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 145 days; Days to treatment end: 146 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 148 days; Days to treatment end: 148 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 225 days; Days to treatment end: 618 days (1.7 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 225 days; Days to treatment end: 253 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 225 days; Days to treatment end: 623 days (1.7 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 253 days; Days to treatment end: 625 days (1.7 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 631 days (1.7 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): M Protein 3.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 87.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.171 mg/dL; Immunoglobulin G 51.6 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 3.4 µg/mL; Lactate Dehydrogenase 4.27 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.72 ×10⁹/L; Platelets 265 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 10.5 g/dL; Glucose 5.61 mmol/L; C-Reactive Protein 0.3 mg/dL.
- Day 85 (ECOG 0): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.707 mg/dL; Immunoglobulin G 13 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.39 g/L; Lactate Dehydrogenase 3.92 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.55 ×10⁹/L; Platelets 299 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 7.1 g/dL; Glucose 4.51 mmol/L.
- Day 184 (ECOG 0): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 14.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.699 mg/dL; Immunoglobulin G 16.7 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.15 g/L; Hemoglobin 6.2 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Albumin 43 g/L; Total Protein 7.3 g/dL; Glucose 6.44 mmol/L.
- Day 281 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.197 mg/dL; Immunoglobulin G 7.59 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 3.48 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.16 ×10⁹/L; Platelets 242 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.35 mmol/L; Albumin 44 g/L; Total Protein 6.7 g/dL; Glucose 4.18 mmol/L.
- Day 379 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.247 mg/dL; Immunoglobulin G 6.27 g/L; Immunoglobulin A 0.66 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 3.62 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.98 ×10⁹/L; Platelets 244 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL; Glucose 4.51 mmol/L.
- Day 464 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.0224 mg/dL; Immunoglobulin G 4.9 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 3.27 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.42 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.45 mmol/L; Albumin 45 g/L; Total Protein 6.7 g/dL; Glucose 5.23 mmol/L.
- Day 576 (ECOG 1): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.157 mg/dL; Immunoglobulin G 3.88 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.86 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 6.2 g/dL; Glucose 4.79 mmol/L.
- Day 659 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.718 mg/dL; Immunoglobulin G 4.71 g/L; Immunoglobulin A 0.35 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 3.33 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.89 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.6 g/dL; Glucose 4.84 mmol/L.

Other clinical attributes
- Day 1: Weight: 52 kg; Height: 161 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Leukemia.
- Relative with cancer history: yes; Relationship type: Maternal Grandfather; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2570_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2570_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
